Gene-level copy-number profile of tumor specimen TCGA-EY-A212-01A from TCGA case TCGA-EY-A212, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary serous cystadenocarcinoma; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 84.0 years (30,680 days).
Specimen TCGA-EY-A212-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.ab417d3f-22ed-4c4f-a239-e14422b6ad5c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EY-A212-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 823 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ec6ff3bf-24e3-4d59-9652-38e6b3d72578

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 13,575; copy number 2: 39,161; copy number 3: 6,199; copy number 4: 335; copy number 5: 359; copy number 6: 52; copy number 7: 93; copy number 13: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EY-A212-01A-11D-A14J-01): tumor purity 0.94, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr4:49,096–305,474, 10 genes: BNIP3P41, ZNF595, AC253576.1, ZNF718, AC253576.2, AC108475.1, ZNF876P, AC079140.3, AC079140.5, ZNF732.
- chr5:60,021,249–60,033,020, 1 gene: AC034234.1.
- chr17:39,546,104–39,567,559, 2 genes: RNU6-233P, AC009283.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 515 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:42,015,625–42,170,301, 3 genes, copy number 5: AC013480.1, PKDCC, EML4-AS1.
- chr3:8,980,591–9,363,053, 1 gene, copy number 5 (within-gene range 2–5): SRGAP3.
- chr3:9,192,493–9,363,303, 5 genes, copy number 5 (within-gene range 2–5): SRGAP3-AS2, SRGAP3-AS3, SRGAP3-AS4, AC026191.1, PGAM1P4.
- chr3:13,650,696–13,746,638, 1 gene, copy number 6 (within-gene range 3–6): LINC00620.
- chr3:107,834,586–107,928,907, 2 genes, copy number 5: LINC00636, LINC00635.
- chr7:16,599,779–17,940,501, 21 genes, copy number 5 (within-gene range 1–5): ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13.
- chr7:19,353,531–19,578,606, 1 gene, copy number 5: AC007091.1.
- chr7:117,604,791–117,874,139, 2 genes, copy number 6 (within-gene range 2–6): AC000061.1, CTTNBP2.
- chr9:3,218,297–3,691,814, 5 genes, copy number 5 (within-gene range 2–5): RFX3, AL354941.1, RFX3-AS1, AL354977.2, AL354977.1.
- chr9:3,875,584–3,878,809, 1 gene, copy number 5: AL137071.1.
- chr9:33,921,693–34,252,523, 14 genes, copy number 6: UBAP2, SNORD121B, SNORD121A, OSTCP8, RN7SKP114, AL354989.1, DCAF12, TUBB4BP2, AL354989.2, UBAP1, RPL35AP2, AL353662.2, RNA5SP282, AL353662.1.
- chr11:101,029,624–101,209,591, 2 genes, copy number 5 (within-gene range 3–5): PGR, PGR-AS1.
- chr16:18,170,356–29,370,272, 309 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr17:38,749,360–38,996,624, 18 genes, copy number 6–13: AC006449.5, PSMB3, RNU6-866P, PIP4K2B, CWC25, MIR4727, C17orf98, RPL23, SNORA21B, SNORA21, AC110749.1, LASP1, AC006441.1, MIR6779, AC006441.3, LINC00672, FBXO47, AC006441.2.
- chr17:39,603,536–40,100,589, 28 genes, copy number 6: NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1.
- chr20:41,712,479–45,579,326, 102 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,727. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
